CPTAC case C3N-02015 — Kidney — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/a176d63e-e9ac-4fe0-8906-051adc48a898

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1962; Vital status: Alive; Country of birth: United States.

Diagnoses (1)
1. Renal cell carcinoma, NOS: ICD-O-3 morphology code: 8312/3; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Age at diagnosis: 54.6 years (19,939 days); Year of diagnosis: 2017; AJCC staging edition: 7th; AJCC clinical M: MX; AJCC pathologic T: T1a; AJCC pathologic N: NX; AJCC pathologic M: M0; AJCC pathologic stage: Stage I; Tumor grade: G2; Residual disease: RX; Last known disease status: Tumor free; Days to last known disease status: 1,383 days (3.8 years); Progression or recurrence: no; Days to last follow up: 1,383 days (3.8 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 3.5 cm (a second GDC size field records 5 cm); Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 1; Margin status: Uninvolved; Sarcomatoid present: No.

Follow-up (5 entries)
- Days to follow up: 296 days; Disease response: Tumor Free.
- Days to follow up: 679 days (1.9 years); Disease response: Tumor Free.
- Days to follow up: 1,234 days (3.4 years); Disease response: Tumor Free.
- Days to follow up: 1,383 days (3.8 years); Disease response: Tumor Free.
- Days to follow up: 1,383 days (3.8 years); Disease response: Complete Response.

Other clinical attributes
- Weight: 78.93 kg; Height: 175.26 cm; BMI: 25.69.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 33; Cigarettes per day: 20; Tobacco smoking onset year: 1983; Tobacco smoking quit year: 2016; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker; Exposure duration years: 33.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-02015-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 252 mg; Time between excision and freezing: 25 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-02015-21: Section location: Middle; Percent tumor nuclei: 85; Percent necrosis: 2.
- Sample C3N-02015-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 0 days; Method of sample procurement: Blood Draw.
